Gene-level copy-number profile of tumor specimen TCGA-X6-A8C3-01A from TCGA case TCGA-X6-A8C3, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 59.6 years (21,751 days).
Specimen TCGA-X6-A8C3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.acb385f3-fc6b-48e1-af09-52a2baa1384f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A8C3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c72783a1-1851-4ec4-8862-cc4764d72447

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2,591; copy number 2: 10,319; copy number 3: 25,844; copy number 4: 12,597; copy number 5: 4,915; copy number 6: 1,533; copy number 7: 1,368; copy number 8: 633.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A8C3-01A-11D-A36I-01): tumor purity 0.53, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:7,613,946–7,711,372, 6 genes: SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,001 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:7,102,573–52,269,569, 728 genes, copy number 7 (broad region; genes not listed).
- chr11:2,328,749–2,377,992, 1 gene, copy number 7 (within-gene range 5–7): CD81-AS1.
- chr11:2,372,638–4,655,488, 101 genes, copy number 7 (broad region; genes not listed).
- chr11:5,253,188–5,678,434, 3 genes, copy number 7 (within-gene range 4–7): HBG2, AC104389.5, HBE1.
- chr11:5,303,444–5,644,398, 28 genes, copy number 7 (within-gene range 4–7): OR51B5, OR51B3P, OR51B2, OR51B8P, OR51B6, AC104389.3, AC104389.4, OR51M1, OR51J1, OR51Q1, OR51K1P, OR51I1, OR51I2, OR51A10P, OR52D1, UBQLN3, UBQLNL, OLFM5P, OR52V1P, OR52H1, OR52H2P, OR52B5P, OR52T1P, HNRNPA1P53, OR52B6, TRIM6, TRIM6-TRIM34, TRIM34.
- chr12:38,646,822–41,072,415, 27 genes, copy number 7 (within-gene range 5–7): CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr13:18,467,172–20,723,098, 76 genes, copy number 7 (broad region; genes not listed).
- chr15:22,664,359–23,856,375, 37 genes, copy number 7: WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P.
- chr18:316,737–15,330,282, 367 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–43,504,935, 633 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,591. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
